CGCI case HTMCP-03-06-02411 — HIV+ Tumor Molecular Characterization Project - Cervical Cancer (CGCI-HTMCP-CC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Epithelial Neoplasms, NOS; Primary site: Cervix uteri. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/18395371-3c84-4d39-8ace-a3546e9ea34e

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 42 years; Vital status: Dead; Days to death: 332 days.

Diagnoses (2)
1. Glassy cell carcinoma (the primary disease): ICD-O-3 morphology code: 8015/3; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 42.2 years (15,398 days); Year of diagnosis: 2016; Method of diagnosis: Biopsy; AJCC clinical T: T1b2; AJCC clinical N: NX; AJCC clinical M: MX; FIGO stage: Stage IB2; FIGO staging edition year: 2009; Tumor grade: GX; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 332 days.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin + Paclitaxel; Initial disease status: Initial Diagnosis; Days to treatment start: 38 days; Days to treatment end: 216 days; Number of cycles: 7; Treatment outcome: Progressive Disease.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Progressive Disease.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.
2. Tumor, NOS: Tissue or organ of origin: Cervix uteri; Classification of tumor: Synchronous primary; Age at diagnosis: 42.7 years (15,587 days); Days to diagnosis: 189 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Follow-up contacts recording only the day: day -2,249, day -9, day 332.

Molecular and laboratory tests
- CDKN2A (IHC): Negative.

Other clinical attributes
- Day -2,249: Risk factors: HIV/AIDS.
- Day -2,249: Comorbidities: HIV/AIDS.
- Day 0: Weight: 47 kg; Height: 162 cm; BMI: 17.9; CD4 count: 417; Haart treatment indicator: Yes; Hormonal contraceptive use: Never Used; Hysterectomy type: Not Performed; Menopause status: Premenopausal; Pregnant at diagnosis: No.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples)
- Sample HTMCP-03-06-02411-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
- Sample HTMCP-03-06-02411-01Z: Sample type: Tumor; Tissue type: Tumor.
- Sample HTMCP-03-06-02411-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: With tumor; Live birth pregnancy count: 5; Total pregnancy count: 5; Tobacco smoking history indicator: 1; Submitted tumor site: Cervical; Method initial path diagnosis: Biopsy (cervical / CT-guided / Other); Hysterectomy Performed Ind-3: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: HIV status: Positive; Year of HIV diagnosis: 2010; Haart therapy at diagnosis: Yes; Haart therapy prior to diagnosis: Yes.
- Follow-up form: New tumor event diagnosis indicator: Yes.
- Follow-up form, New tumor event: New tumor event type: New Primary Tumor; New tumor event site other: left cervical; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Paclitaxel + Cisplatin; Pharma adjuvant cycles count: 7; Treatment best response: Clinical Progressive Disease.
